CCDI case PBCVLZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/0bead809-da94-4dbb-b348-43f38c6693b4

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Sample 0E1FGM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1FGT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
